Somatic mutation profile of tumor specimen TCGA-62-A46Y-01A (aliquot TCGA-62-A46Y-01A-11D-A24D-08) from TCGA case TCGA-62-A46Y, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma with mixed subtypes; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 70.9 years (25,905 days).
Specimen TCGA-62-A46Y-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 18ec59c0-c051-4c4d-8829-d978f1242741.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-62-A46Y-10A (Blood Derived Normal), aliquot TCGA-62-A46Y-10A-01D-A24F-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a37b6c13-f8e1-4cfb-916d-72eb2d117c03

The open-access MAF lists 36 somatic variants for this specimen: 32 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 25, Nonsense Mutation 4, Silent 4, Frame Shift Del 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.581T>G p.L194R | Missense Mutation (SNP) | VAF 30/72 reads (42%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519998, COSV52663681, COSV52677924, COSV52679257, COSV52713187; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- ABI3BP | c.185G>A p.G62E | Missense Mutation (SNP) | VAF 7/76 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs753741511, COSV52536911; called by muse, mutect2, varscan2
- ATM | c.4320A>C p.K1440N | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.49); PolyPhen benign (0.062); catalogued as COSV99590076; called by muse, mutect2, varscan2
- CFAP74 | c.2161G>A p.E721K | Missense Mutation (SNP) | VAF 27/150 reads (18%) | SIFT tolerated (0.63); PolyPhen benign (0.043); catalogued as COSV54565132; called by muse, mutect2, varscan2
- CNTNAP2 | c.259G>T p.V87F | Missense Mutation (SNP) | VAF 19/124 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.973); catalogued as COSV100667201; called by muse, mutect2, varscan2
- DPEP2 | c.1172G>T p.G391V | Missense Mutation (SNP) | VAF 62/274 reads (23%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.739); catalogued as COSV99263157; called by muse, mutect2, varscan2
- DUS4L-BCAP29 | c.1075C>T p.R359C | Missense Mutation (SNP) | VAF 9/106 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs780919779, COSV50052278; called by muse, mutect2
- FGF7 | c.217A>G p.T73A | Missense Mutation (SNP) | VAF 17/88 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.56); catalogued as COSV99983458; called by muse, mutect2, varscan2
- GABRA5 | c.167T>G p.L56R | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100165298; called by muse, mutect2, varscan2
- IGDCC4 | c.3040G>A p.A1014T | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as rs756832202, COSV100732942; called by muse, mutect2, varscan2
- IQSEC2 | c.3223G>A p.D1075N (on ENST00000642864 / NM_001111125.3; = p.D870N on NM_015075.2) | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); catalogued as COSV64724533; called by muse, mutect2
- KDM3B | c.1815C>G p.F605L | Missense Mutation (SNP) | VAF 39/167 reads (23%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.168); catalogued as COSV100069794; called by muse, mutect2, varscan2
- KIAA0319L | c.1303G>T p.D435Y | Missense Mutation (SNP) | VAF 25/118 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100357434; called by muse, mutect2, varscan2
- KIAA1210 | c.2671G>C p.V891L | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.391); catalogued as COSV101274237; called by muse, mutect2, varscan2
- LRP1B | c.1081C>T p.R361* | Nonsense Mutation (SNP) | VAF 19/97 reads (20%) | catalogued as COSV101256443, COSV67254380; called by muse, mutect2, varscan2
- LTBP2 | c.4502G>A p.R1501Q | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs373693540; called by muse, mutect2, varscan2
- MROH9 | c.371T>G p.L124* | Nonsense Mutation (SNP) | VAF 7/24 reads (29%) | catalogued as rs1245668477, COSV100882803; called by muse, mutect2, varscan2
- NLRP14 | c.1461dup p.A488Cfs*22 | Frame Shift Ins (INS) | VAF 18/136 reads (13%) | catalogued as rs762290589; called by mutect2, pindel, varscan2
- NPEPPS | c.2200G>T p.E734* | Nonsense Mutation (SNP) | VAF 17/91 reads (19%) | catalogued as COSV100443764; called by muse, mutect2, varscan2
- OR10G7 | c.707C>A p.A236D | Missense Mutation (SNP) | VAF 18/150 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV57865797; called by muse, mutect2, varscan2
- PCDHB2 | c.1058C>A p.T353K | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.001); catalogued as COSV99165453; called by muse, mutect2, varscan2
- RET | c.2269G>A p.V757M | Missense Mutation (SNP) | VAF 29/258 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100393826; called by muse, mutect2, varscan2
- RHOXF1 | c.16G>A p.V6I | Missense Mutation (SNP) | VAF 19/93 reads (20%) | SIFT tolerated, low confidence (0.89); PolyPhen benign (0); catalogued as rs931167506, COSV99483843; called by muse, mutect2, varscan2
- RPAP1 | c.1319A>C p.D440A | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100427174, COSV58543202; called by muse, mutect2, varscan2
- RTL9 | c.832T>C p.S278P | Missense Mutation (SNP) | VAF 59/249 reads (24%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as COSV101511709; called by muse, mutect2, varscan2
- SF3A1 | c.465T>G p.D155E | Missense Mutation (SNP) | VAF 10/142 reads (7%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.935); catalogued as COSV99305504; called by muse, mutect2
- STAT2 | c.2435T>C p.I812T | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.014); catalogued as COSV99950681; called by muse, mutect2, varscan2
- TNFAIP6 | c.752C>A p.S251Y | Missense Mutation (SNP) | VAF 25/128 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.172); catalogued as COSV54640893, COSV99693921; called by muse, mutect2, varscan2
- ZFYVE28 | c.1475A>C p.E492A | Missense Mutation (SNP) | VAF 18/128 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.493); catalogued as COSV99343073; called by muse, mutect2, varscan2
- FBN2 | c.6381del p.C2128Vfs*121 | Frame Shift Del (DEL) | VAF 17/112 reads (15%) | called by mutect2, pindel*, varscan2
- KDM6A | c.2098_2099del p.S700Lfs*29 | Frame Shift Del (DEL) | VAF 10/46 reads (22%) | called by pindel, varscan2
- ZNF431 | c.695dup p.Y232* | Nonsense Mutation (INS) | VAF 24/88 reads (27%) | called by mutect2, pindel, varscan2
- DLL1 | c.1968C>T p.D656= | Silent (SNP) | VAF 18/65 reads (28%) | catalogued as rs144070852, COSV64536703, COSV64537116; ClinVar: likely benign; called by muse, mutect2, varscan2
- LRRC8E | c.1707G>A p.G569= | Silent (SNP) | VAF 11/135 reads (8%) | catalogued as COSV100142982; called by muse, mutect2
- SORL1 | c.5130C>T p.I1710= | Silent (SNP) | VAF 8/49 reads (16%) | catalogued as COSV99494230; called by muse, mutect2, varscan2
- SPTBN1 | c.4362C>T p.D1454= | Silent (SNP) | VAF 37/206 reads (18%) | catalogued as rs540844973, COSV100442818; called by muse, mutect2, varscan2
